Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A9DK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A9DK-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME:		SURG PATH #:
MR #:		SPECIMEN CLASS:
BILLING #:		ALT ID #:
LOCATION:		DATE OF PROCEDURE:
AGE:	SEX: M	DATE RECEIVED:
DOB:		TIME RECEIVED:
PHYSICIAN:		DATE OF REPORT:
COPY TO:		DATE OF PRINTING:

Material Received:

A: Pelvic lymph node - left
B: Pelvic lymph node - right
C: Prostate

ICD-0 3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/26/14

History:

A -year-old male with a clinical history of prostate cancer.

Final Diagnosis:

- A. Fibroadipose tissue, "left pelvic", biopsy: There is no evidence of malignancy. No lymph node is seen.
- B. Fibroadipose tissue, "right pelvic", biopsy: There is no evidence of malignancy. No lymph node is seen.
- C. Prostate, prostatectomy: Prostatic adenocarcinoma, Gleason grade 4+4 (Score 8), involving bilateral lobes and 30% of the prostate, with extensive perineural invasion.

Comment:

Prostate Cancer Checklist:

Procedure: Prostatectomy

Histologic Type: Adenocarcinoma

Histologic Grade: Poorly differentiated

Gleason Pattern

Primary Pattern: 4

Secondary Pattern: 4

Tertiary Pattern (if higher than primary and secondary): N/A

Total Gleason Score (Primary + Secondary): 8

Proportion (percent) of prostate involved by tumor: 30%

Tumor Multicentricity: Yes

Extraprostatic Extension: No

Seminal Vesicle Invasion: No

Margins: Negative for malignancy, however, the tumor approaches to within 1 mm of inked right lobe capsular margin in multiple foci.

Perineural Invasion: Yes

Vascular Invasion: No

Additional Pathologic Findings: Glandular atrophy

Lymph Nodes: 0

Gross Picture Taken: No

MR #:

Page 1 of 2

SURGICAL PATHOLOGY REPORT

Date of Printing:

Order Number:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Pathologic Staging: pT2c, pNX, pMX

Primary Tumor (pT)
pT2c: Bilateral disease

Regional Lymph Nodes (pN)
pNX: Cannot be assessed

Distant Metastasis (pM)
pMX: Distant metastasis cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at _____ this case has been concurrently reviewed by the following pathologist: Dr. _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled "pelvic lymph node – left" is a 1.3 x 0.5 x 0.1 cm piece of yellow-red fatty tissue. The specimen is submitted entirely for frozen and permanent sections as A1FS.

B. Received fresh labeled "pelvic lymph node – right" is a 2.0 x 2.0 x 0.6 cm piece of red-yellow soft tissue. The specimen is submitted entirely for frozen and permanent section as B1FS.

C. Received in formalin labeled "prostate" is a 22 gram prostate measuring 3.0 cm from right to left, 2.3 cm from anterior to posterior, 2.3 cm from superior to inferior. The right seminal vesicle measures 1.5 cm in length and 0.3 cm in diameter. The left seminal vesicle measures 2.3 cm in length and 0.3 cm in diameter. The external surface of the prostate is tan-pink and ragged. Some tissue has been removed for research from the posterior aspect. The right side of the prostate is inked black and the left side is inked blue. The prostate is serially sectioned to reveal a nodular cut surface. The specimen is submitted as follows:

- C1 - Right bladder neck margin (serially sectioned).
- C2 - Left bladder neck margin (serially sectioned).
- C3 - Right distal urethral margin (serially sectioned).
- C4 - Left distal urethral margin (serially sectioned).
- C5 - Right and left seminal vesicle margin.
- C6 - Representative sections from the right midanterior prostate.
- C7 - Representative sections from the left midanterior prostate.
- C8 through C16 – Entire posterior right lobe, from apex to base.
- C17 through C23 – Entire posterior left lobe, from apex to base.

Intraoperative Consultation:

A1FS, soft tissue, "pelvic lymph node":
No lymph node is identified.

B1FS, soft tissue, "pelvic lymph node":
No lymph node is identified.
Attending Physician

MR #:

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file d4b6d230-03b7-4a9d-aa5b-bdb070190602 (TCGA-XJ-A9DK.67B87CD1-3C76-47DD-93B9-BB9ADCF64404.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).